CCDI case PBCGEE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d3b41c93-4465-49d7-943c-d62a223ad8a1

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.1 years (750 days).

Biospecimens (3 samples)
- Sample 0DR7Y3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR7Y8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DR7YF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
